Gene-level copy-number profile of tumor specimen TCGA-FF-8047-01A from TCGA case TCGA-FF-8047, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 38.3 years (13,996 days).
Specimen TCGA-FF-8047-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.5b1bff34-5c81-4139-9f22-01c256754e2d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FF-8047-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9bf2c78a-da7d-42d9-81e0-213b4cd546d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 8,537; copy number 2: 47,833; copy number 3: 3,431.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FF-8047-01A-11D-2209-01): tumor purity 0.93, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,824,213, 14 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,116. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
